Somatic mutation profile of tumor specimen TCGA-06-A7TK-01A (aliquot TCGA-06-A7TK-01A-21D-A391-08) from TCGA case TCGA-06-A7TK, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 64.8 years (23,674 days).
Specimen TCGA-06-A7TK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4890e0af-0189-4ec4-aaf0-cf302fe1776f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-A7TK-10A (Blood Derived Normal), aliquot TCGA-06-A7TK-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/beef6d8f-5519-4002-9159-b17977a383e6

The open-access MAF lists 63 somatic variants for this specimen: 44 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 18, Frame Shift Del 3, Intron 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR3B | c.938G>T p.R313L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55447175, COSV99753974; called by muse, mutect2, varscan2
- ADGRE3 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as rs760712152, COSV53730327; called by muse, mutect2, varscan2
- C4B | c.2509C>T p.L837F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1012400686, COSV101426129; called by mutect2, varscan2
- CIC | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV99359512; called by muse, mutect2, varscan2
- CLEC9A | c.515A>G p.D172G | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV100191410; called by muse, mutect2, varscan2
- CNTNAP2 | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1375981068, COSV100673045, COSV62211214; called by muse, mutect2, varscan2
- CRISP1 | c.583T>G p.C195G | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749526645, COSV100236834; called by muse, mutect2, varscan2
- DAGLA | c.329T>C p.I110T | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs1299071635, COSV99944332; called by muse, mutect2, varscan2
- DSCAML1 | c.2195G>A p.S732N (on ENST00000321322; = p.S672N on NM_020693.4) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.637); catalogued as COSV100355818; called by muse, mutect2, varscan2
- EHMT2 | c.2030A>G p.N677S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as rs1157136700, COSV100977189; called by muse, mutect2, varscan2
- EXOC2 | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV100033521, COSV57872065; called by muse, mutect2, varscan2
- FIZ1 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1222917710, COSV99684560; called by muse, mutect2, varscan2
- FOXR1 | c.562A>G p.N188D | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100392900; called by muse, mutect2, varscan2
- GRM7 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as rs767400612, COSV63134452; called by muse, mutect2, varscan2
- HIF3A | c.1607A>T p.E536V (on ENST00000377670 / NM_152795.4; = p.E467V on NM_022462.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV99355729; called by muse, mutect2, varscan2
- HNMT | c.13A>C p.M5L | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99698562; called by muse, mutect2, varscan2
- KCNT1 | c.341G>A p.R114H (on ENST00000488444; = p.R133H on NM_020822.3) | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201295824, COSV99705676; ClinVar: uncertain significance; called by muse, mutect2
- LPAR1 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1188890764, COSV62688188; called by muse, mutect2, varscan2
- MAGEB16 | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs769654089, COSV101303301, COSV67874292; called by muse, mutect2, varscan2
- MED12 | c.2860G>A p.V954I | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.903); catalogued as COSV100377831; called by muse, mutect2, varscan2
- MUC16 | c.41227G>A p.D13743N | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.968); catalogued as COSV101109881; called by muse, mutect2, varscan2
- NPEPL1 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192958323, COSV100622415; called by muse, mutect2, varscan2
- OR8J3 | c.296C>G p.T99S | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV100040604, COSV100040796, COSV56881853; called by muse, mutect2, varscan2
- PCLO | c.7698_7700del p.N2566del | In Frame Del (DEL) | VAF 24/100 reads (24%) | catalogued as rs775434913; called by pindel, varscan2
- PDHA2 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769918894, COSV54779080, COSV54779524; called by muse, mutect2, varscan2
- PIK3CG | c.2412G>A p.M804I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs370847658, COSV100782842, COSV63248790; called by muse, mutect2, varscan2
- PLCG2 | c.125C>G p.T42S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV100842269; called by muse, mutect2, varscan2
- PLCXD3 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs559527240, COSV60607794; called by muse, mutect2, varscan2
- POTEE | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs549442993, COSV100387802, COSV58230646; called by muse, mutect2, varscan2
- PPP1R16B | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100239356; called by muse, mutect2, varscan2
- QTRT2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99846891; called by muse, mutect2, varscan2
- RECK | c.1632G>C p.Q544H | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV100937479; called by muse, mutect2, varscan2
- RSPH14 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs199729382; called by mutect2, varscan2
- SCTR | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs572299359, COSV50033601; called by muse, mutect2, varscan2
- SESTD1 | c.1848G>T p.Q616H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.205); catalogued as COSV100090460; called by muse, mutect2, varscan2
- SLC43A3 | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100725187; called by muse, mutect2, varscan2
- SMYD1 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV70225338; called by muse, mutect2, varscan2
- SV2B | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs372020741; called by muse, mutect2, varscan2
- TICRR | c.2838G>C p.E946D | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV99176396; called by muse, mutect2, varscan2
- TUSC3 | c.427-2A>T p.X143_splice | Splice Site (SNP) | VAF 10/60 reads (17%) | catalogued as COSV101141320; called by muse, varscan2
- ZNF205 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs1299003619, COSV99530374; called by muse, mutect2, varscan2
- SERPINB5 | c.171del p.L58Ffs*16 | Frame Shift Del (DEL) | VAF 26/97 reads (27%) | called by mutect2, pindel, varscan2
- SLITRK2 | c.726_729del p.C243Rfs*11 | Frame Shift Del (DEL) | VAF 45/69 reads (65%) | called by mutect2, pindel, varscan2
- SMARCC2 | c.3065del p.P1022Hfs*39 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- ADAMDEC1 | c.579C>T p.D193= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as rs141288918; called by muse, mutect2, varscan2
- ATAD5 | c.1845C>T p.D615= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs377200900; called by muse, mutect2, varscan2
- ATP6V1F | c.108C>T p.F36= | Silent (SNP) | VAF 31/131 reads (24%) | catalogued as COSV99925983; called by muse, mutect2, varscan2
- CAD | c.1626G>A p.Q542= | Silent (SNP) | VAF 64/168 reads (38%) | catalogued as COSV99254962; called by muse, mutect2, varscan2
- CD37 | c.561C>G p.T187= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100114997; called by muse, mutect2, varscan2
- DEPTOR | c.462G>A p.R154= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99638489; called by muse, mutect2, varscan2
- DNAH2 | c.11004C>T p.Y3668= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs185083349, COSV101209269; called by muse, mutect2, varscan2
- ERICH3 | c.3951C>T p.D1317= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV100444206; called by muse, mutect2, varscan2
- IL10RA | c.1539G>A p.T513= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs372503247; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KCTD16 | c.438C>T p.S146= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs147117374; called by muse, mutect2, varscan2
- KIF23 | c.2487A>G p.Q829= (on ENST00000260363; = p.Q725= on NM_004856.7) | Silent (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- OR4C13 | c.105C>T p.N35= | Silent (SNP) | VAF 55/142 reads (39%) | catalogued as rs782181373, COSV101634176, COSV73648784, COSV73648947; called by muse, mutect2, varscan2
- PCNT | c.7545C>T p.S2515= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100855443; called by muse, mutect2, varscan2
- PDZD7 | c.183A>G p.S61= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99827478; called by muse, mutect2, varscan2
- PLXNA4 | c.3573C>T p.T1191= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs889502891, COSV100324043; called by muse, mutect2, varscan2
- SLC6A17 | c.1887G>A p.T629= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs139019064, COSV58995443; called by muse, mutect2, varscan2
- USH1C | c.1500C>T p.D500= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs139787873; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF236 | c.36G>T p.L12= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV99470258, COSV99470461; called by muse, mutect2, varscan2
- OBSCN | c.11659+4422G>A | Intron (SNP) | VAF 10/110 reads (9%) | catalogued as rs746064999, COSV52849948; called by muse, mutect2
